Gene-level copy-number profile of tumor specimen MP2PRT-PANUYZ-TMP1-A from MP2PRT case MP2PRT-PANUYZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (676 days).
Specimen MP2PRT-PANUYZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8c8e85f0-10df-4a2c-bfcb-562e8993e50c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANUYZ-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/17b1eff4-fc1f-41a4-9c89-7d6b8329dfc4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 3,104; copy number 2: 54,074; copy number 3: 1,651.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.
- chr14:105,851,705–106,258,223, 77 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
